Somatic mutation profile of tumor specimen TCGA-HQ-A5NE-01A (aliquot TCGA-HQ-A5NE-01A-12D-A289-08) from TCGA case TCGA-HQ-A5NE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 56.5 years (20,647 days).
Specimen TCGA-HQ-A5NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16c2f25f-336b-455d-8af4-69e52f253687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HQ-A5NE-10A (Blood Derived Normal), aliquot TCGA-HQ-A5NE-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85c8e1e9-2538-4e97-b8c7-a1453a9ba1c8

The open-access MAF lists 405 somatic variants for this specimen: 290 protein-altering or splice-affecting, 104 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 256, Silent 104, Nonsense Mutation 25, Intron 5, Frame Shift Del 4, RNA 3, Splice Region 2, Frame Shift Ins 1, Translation Start Site 1, 5'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4218G>C p.Q1406H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV57332742, COSV57354402, COSV57377402; called by muse, mutect2, varscan2
- ERBB3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 53/142 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV57246601, COSV57252959; called by muse, mutect2, varscan2
- KCNH2 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199472944, CM970803, CX097836, COSV51224186; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2056C>T p.P686S (on ENST00000272895 / NM_173076.3; = p.P368S on NM_015657.3) | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.228); catalogued as COSV55973536; called by muse, mutect2, varscan2
- ABCA13 | c.4795C>T p.H1599Y | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV70035354; called by muse, mutect2
- ABCB1 | c.443G>C p.R148T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55962025; called by muse, mutect2, varscan2
- ABCC8 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765626111, COSV56856749; called by muse, mutect2, varscan2
- ACTN4 | c.2705C>G p.S902C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53146006, COSV53149958; called by muse, mutect2, varscan2
- ADCY2 | c.2557C>A p.R853S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57896656; called by muse, mutect2, varscan2
- AGO2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV55052245; called by muse, mutect2, varscan2
- AKT2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV60910156; called by muse, mutect2, varscan2
- ANAPC5 | c.900G>C p.L300F | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV55845125; called by muse, mutect2, varscan2
- ANK2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52179389; called by muse, mutect2
- ANKRD12 | c.3204G>C p.K1068N | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100042101, COSV50844272; called by muse, mutect2, varscan2
- ANKS1B | c.2426G>A p.R809K (on ENST00000547776 / NM_152788.4; = p.R35K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1261340016, COSV60357004, COSV60360483; called by muse, mutect2, varscan2
- ANKZF1 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as rs747740100, COSV55478605; called by muse, mutect2, varscan2
- ARHGAP20 | c.2585del p.G862Efs*42 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | catalogued as COSV52818807; called by mutect2, pindel, varscan2
- ARHGAP9 | c.2027C>G p.S676* (on ENST00000393797 / NM_001319850.2; = p.S657* on NM_032496.4) | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99953510; called by muse, mutect2, varscan2
- ARHGEF12 | c.3952G>A p.G1318R | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.018); catalogued as COSV63107068; called by muse, mutect2, varscan2
- ARHGEF19 | c.1982A>G p.Q661R | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1460410139, COSV54618467; called by muse, mutect2, varscan2
- ARID4B | c.2947G>C p.E983Q | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as COSV51610100, COSV51611617; called by muse, mutect2, varscan2
- ARMC5 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV51659570; called by muse, varscan2
- ARMC6 | c.399G>C p.Q133H (on ENST00000392336; = p.Q108H on NM_033415.4) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV54183512, COSV54183942; called by muse, mutect2, varscan2
- ARMC7 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV55461924, COSV55461999; called by muse, mutect2, varscan2
- ASXL1 | c.4576G>A p.D1526N | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60120761; called by muse, mutect2
- ATAD2 | c.3416C>G p.S1139* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99783846; called by muse, mutect2, varscan2
- ATAD5 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV58978287; called by muse, mutect2, varscan2
- ATN1 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV63112840; called by muse, mutect2, varscan2
- ATP13A3 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99755856; called by muse, mutect2
- ATRN | c.3641C>G p.S1214* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | catalogued as COSV99496324; called by muse, mutect2
- BPIFB3 | c.1340G>C p.G447A | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64958091; called by muse, mutect2, varscan2
- BRPF1 | c.2770G>C p.G924R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV57407488; called by muse, mutect2, varscan2
- BTAF1 | c.2476C>G p.Q826E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56438894; called by muse, mutect2, varscan2
- BTAF1 | c.5407G>A p.D1803N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99794661; called by muse, mutect2
- C14orf39 | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as rs1413542870, COSV58784685; called by muse, mutect2, varscan2
- C2CD2L | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV60884713; called by muse, mutect2
- C2orf16 | c.4691G>C p.R1564T | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV100820623, COSV62678024; called by muse, mutect2
- C3 | c.1523G>C p.R508P | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55580515, COSV55581357, COSV99836146; called by muse, mutect2, varscan2
- C9orf153 | c.196T>C p.F66L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV59252331; called by muse, mutect2, varscan2
- CACNA1C | c.1369G>C p.D457H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100214018; called by muse, mutect2
- CACNA2D1 | c.2506G>A p.G836S (on ENST00000356253 / NM_001366867.1; = p.G824S on NM_000722.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV62390926; called by muse, mutect2, varscan2
- CADM3 | c.1096G>C p.E366Q (on ENST00000368125 / NM_001127173.3; = p.E400Q on NM_021189.5) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63674437; called by muse, mutect2, varscan2
- CALCOCO1 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV50421958; called by muse, mutect2, varscan2
- CAPRIN2 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 24/147 reads (16%) | catalogued as COSV99195396; called by muse, mutect2, varscan2
- CBX2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs1555830980, COSV53970129; called by muse, mutect2, varscan2
- CCDC85A | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV101339329; called by muse, mutect2, varscan2
- CCDC86 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57126246, COSV99920321; called by muse, mutect2, varscan2
- CCHCR1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 143/501 reads (29%) | catalogued as COSV100885457, COSV66182813; called by muse, mutect2, varscan2
- CDH6 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs867559623, COSV54067477; called by muse, mutect2
- CDHR5 | c.1955C>G p.S652W (on ENST00000358353 / NM_001171968.2; = p.S658W on NM_021924.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs752747793, COSV57645867; called by muse, mutect2, varscan2
- CEACAM5 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV55754637; called by muse, mutect2, varscan2
- CENPF | c.5412G>A p.M1804I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104423719, COSV65278634; called by muse, mutect2, varscan2
- CEP112 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101210347; called by muse, mutect2
- CERCAM | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65711808; called by muse, mutect2, varscan2
- CERCAM | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777311053, COSV65711813; called by muse, varscan2
- CFAP61 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.423); catalogued as COSV99842419; called by muse, mutect2, varscan2
- CLCN3 | c.627G>C p.M209I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV61628404; called by muse, mutect2, varscan2
- CLYBL | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV59228064; called by muse, mutect2
- COL25A1 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV101210952; called by muse, mutect2, varscan2
- COL4A4 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61632832, COSV61636060; called by muse, mutect2, varscan2
- CPN2 | c.1583G>C p.S528T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV60471617; called by muse, mutect2
- CUBN | c.10417C>G p.L3473V | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.232); catalogued as COSV64725778; called by muse, mutect2, varscan2
- CYP2A6 | c.60G>C p.L20F | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.104); catalogued as rs746024795, COSV56534794; called by muse, mutect2, varscan2
- CYTH1 | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV63123217, COSV63123481; called by muse, mutect2
- DAAM1 | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs538723318, COSV62839486; called by muse, mutect2, varscan2
- DCAF4 | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs17856584, COSV62320454; called by muse, mutect2, varscan2
- DDX19B | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV99849710; called by muse, mutect2, varscan2
- DEFB128 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 71/243 reads (29%) | catalogued as COSV100544383, COSV57685616; called by muse, mutect2, varscan2
- DENND2D | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62959966; called by muse, mutect2, varscan2
- DENND4C | c.1733G>C p.R578T | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV66823206; called by muse, mutect2, varscan2
- DENND4C | c.2956G>A p.E986K (on ENST00000434457 / NM_001330640.2; = p.E937K on NM_017925.7) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV66819856, COSV66820270; called by muse, mutect2, varscan2
- DGKH | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs986549201, COSV54928365; called by muse, mutect2, varscan2
- DHX9 | c.1874C>G p.S625C | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV62361929; called by muse, mutect2, varscan2
- DMRTA1 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV57925351; called by muse, mutect2, varscan2
- DMXL2 | c.3923G>C p.R1308T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV51854884; called by muse, mutect2, varscan2
- DNAJC10 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1261719909, COSV51145895; called by muse, mutect2, varscan2
- DNHD1 | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54442570, COSV54445664; called by muse, mutect2, varscan2
- DNHD1 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as COSV54442830; called by muse, mutect2, varscan2
- DNM2 | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100116301; called by muse, mutect2, varscan2
- DOC2A | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV58752540; called by muse, mutect2, varscan2
- EARS2 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54843036, COSV54843089; called by muse, mutect2, varscan2
- EGLN2 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.194); catalogued as COSV58281129, COSV58281277; called by muse, mutect2, varscan2
- EIF3D | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53405239; called by muse, varscan2
- EMP2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV63996579; called by muse, mutect2, varscan2
- EPRS1 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV65101338; called by muse, mutect2, varscan2
- ESYT1 | c.1767G>T p.M589I | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57276023; called by muse, mutect2, varscan2
- ESYT1 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 63/283 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57276039; called by muse, varscan2
- EXOC2 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.292); catalogued as COSV57871324; called by muse, mutect2
- FABP9 | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100986938, COSV66911794; called by muse, mutect2, varscan2
- FAM135B | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1440100151, COSV52750269; called by muse, mutect2
- FAM193B | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV61558841; called by muse, mutect2, varscan2
- FANCA | c.3308C>A p.A1103D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV59798309; called by muse, mutect2
- FAR2 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs775428447, COSV51723267, COSV51723679; called by muse, mutect2, varscan2
- FAT4 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV67898374; called by muse, mutect2, varscan2
- FHOD3 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV57187002; called by muse, mutect2, varscan2
- FILIP1L | c.1576C>G p.Q526E (on ENST00000354552 / NM_182909.3; = p.Q286E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV100495998; called by muse, mutect2
- FNDC1 | c.2857C>G p.Q953E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV51946947; called by muse, mutect2, varscan2
- FYCO1 | c.3464C>G p.S1155* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99944996; called by muse, mutect2, varscan2
- GALNTL6 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV72493334; called by muse, mutect2, varscan2
- GIMAP2 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV56236205; called by muse, mutect2, varscan2
- GLG1 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 77/182 reads (42%) | catalogued as COSV99215085; called by muse, mutect2, varscan2
- GLUD1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | catalogued as COSV53281460, COSV99517804; called by muse, mutect2
- GNAI1 | c.938G>C p.R313T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV63524916; called by muse, mutect2, varscan2
- GPHN | c.1525G>A p.E509K (on ENST00000315266 / NM_001377519.1; = p.E542K on NM_020806.5) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59478547; called by muse, mutect2
- HDLBP | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100189614; called by muse, mutect2, varscan2
- HECTD3 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 96/241 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV55801819; called by muse, mutect2, varscan2
- HEMGN | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.342); catalogued as COSV52327971, COSV99412418; called by muse, varscan2
- HEMGN | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV52327985; called by muse, varscan2
- HERC1 | c.12044G>T p.R4015I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); catalogued as COSV71249950; called by muse, mutect2, varscan2
- HFM1 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs757823691, COSV54036057; called by muse, mutect2, varscan2
- HMGCS1 | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV57291409; called by muse, mutect2, varscan2
- HSPA6 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | catalogued as rs763881216, COSV100553755, COSV59061575; called by muse, mutect2, varscan2
- HYKK | c.968C>G p.S323C | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV66460480; called by muse, mutect2
- IDH1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as COSV61638939; called by muse, mutect2, varscan2
- IGSF11 | c.661A>G p.I221V (on ENST00000393775 / NM_001015887.3; = p.I220V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as rs764965446, COSV61177704; called by muse, mutect2, varscan2
- IKZF4 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56271287, COSV56271635; called by muse, mutect2, varscan2
- IL22RA2 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as COSV51664616; called by muse, mutect2, varscan2
- IRF2BP2 | c.1760C>G p.S587W | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV64015592; called by muse, mutect2, varscan2
- IRF2BP2 | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as rs748596575, COSV64015596; called by muse, mutect2, varscan2
- IRX1 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.431); catalogued as rs762656812, COSV57361969, COSV57362140; called by muse, mutect2, varscan2
- ITGA8 | c.2890G>C p.D964H | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.522); catalogued as rs1358052662, COSV100958610, COSV65235701; called by muse, mutect2
- KAT6B | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.04); catalogued as rs77402118, COSV54753809; called by muse, mutect2, varscan2
- KCNF1 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54465448; called by mutect2, varscan2
- KIAA1755 | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54080135; called by muse, mutect2, varscan2
- KIF21B | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs1023850106, COSV59765094; called by muse, mutect2, varscan2
- KLHL17 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1344588308, COSV58533410; called by muse, mutect2, varscan2
- KRT5 | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52860097, COSV52863141; called by muse, mutect2, varscan2
- KSR2 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV56682083; called by muse, mutect2, varscan2
- LDHB | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV63365384, COSV63365484; called by muse, mutect2
- LPCAT1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as rs770282686, COSV52040904; called by muse, mutect2, varscan2
- LPO | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV51862118; called by muse, mutect2, varscan2
- LRRCC1 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.275); catalogued as COSV64485464; called by muse, mutect2
- LRRIQ1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1458302370, COSV67837534; called by muse, mutect2, varscan2
- LRRIQ1 | c.2965G>A p.D989N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.601); catalogued as COSV67837541, COSV67840189; called by muse, mutect2, varscan2
- LRWD1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52960381; called by muse, mutect2
- LTBP4 | c.518C>T p.P173L (on ENST00000308370 / NM_001042544.1; = p.P136L on NM_003573.2) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV52589497; called by muse, mutect2, varscan2
- MAGEA6 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1221344440, COSV61449407; called by muse, mutect2, varscan2
- MAN2C1 | c.228-1G>C p.X76_splice | Splice Site (SNP) | VAF 15/112 reads (13%) | catalogued as COSV51227362, COSV51241340; called by muse, mutect2, varscan2
- MAP4 | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 18/192 reads (9%) | catalogued as COSV100805250; called by muse, mutect2
- MARF1 | c.3075G>A p.L1025= | Splice Region (SNP) | VAF 6/104 reads (6%) | catalogued as COSV60028391; called by muse, mutect2
- MECOM | c.1226C>T p.S409L (on ENST00000468789 / NM_001105078.4; = p.S597L on NM_004991.4) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs745981639, COSV52959395; called by muse, mutect2
- MED29 | c.385G>A p.E129K (on ENST00000615911; = p.E108K on NM_017592.4) | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as rs1479765796, COSV55396001; called by muse, mutect2
- MICALL1 | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53243162, COSV99317493; called by muse, mutect2, varscan2
- MRC2 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.695); catalogued as COSV57643966; called by muse, mutect2, varscan2
- MTCH2 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56768743; called by muse, mutect2, varscan2
- MTHFD1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as rs903799100, COSV53703328; called by muse, mutect2, varscan2
- MTRR | c.649C>G p.Q217E (on ENST00000264668; = p.Q190E on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV52946525; called by muse, mutect2
- MUC16 | c.5707G>A p.E1903K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67489702; called by muse, mutect2, varscan2
- MUC16 | c.3921G>A p.M1307I | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV67489709; called by muse, mutect2
- MUC21 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 38/646 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.747); catalogued as rs1318142711, COSV100888841, COSV66222102; called by muse, mutect2
- MXRA5 | c.6482G>T p.G2161V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99475261; called by muse, mutect2, varscan2
- MYBPC1 | c.3391G>A p.E1131K (on ENST00000550270 / NM_206820.2; = p.E1138K on NM_002465.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV62257160; called by muse, mutect2, varscan2
- MYH10 | c.4731G>C p.E1577D | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV52610023; called by muse, varscan2
- MYH9 | c.1383G>C p.L461= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as COSV53392446; called by muse, mutect2
- MYO10 | c.5273G>C p.R1758P | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57029245; called by muse, mutect2, varscan2
- NCOA7 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV57659962; called by muse, mutect2, varscan2
- NDUFA6 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV68913301; called by muse, mutect2, varscan2
- NFATC3 | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60478881; called by muse, mutect2, varscan2
- NFATC4 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 48/106 reads (45%) | catalogued as COSV99144177; called by muse, mutect2, varscan2
- NFIB | c.807C>G p.S269R | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV66627932; called by muse, mutect2, varscan2
- NOTCH1 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1037236860, COSV53036803, COSV53081435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRDE2 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs201538300, COSV62962744; called by muse, mutect2, varscan2
- NRG1 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs146885321, COSV55174404; called by muse, mutect2, varscan2
- OBSCN | c.11743G>A p.E3915K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779979023, COSV52822399; called by muse, mutect2, varscan2
- OR10H5 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1488329047, COSV58279126; called by muse, mutect2, varscan2
- OR4A15 | c.901A>T p.S301C | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV100124195, COSV59037467; called by muse, mutect2, varscan2
- OR4P4 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as COSV58923469; called by muse, mutect2, varscan2
- OXSM | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs746624121, COSV55002549; called by muse, varscan2
- PAPOLG | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.065); catalogued as COSV53185352; called by muse, mutect2
- PARD3B | c.2839G>A p.D947N (on ENST00000406610 / NM_001302769.2; = p.D878N on NM_057177.7) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62528401; called by muse, mutect2
- PARP2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as COSV51641832; called by muse, mutect2, varscan2
- PARP9 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs559272508, COSV64451765; called by muse, mutect2, varscan2
- PCBP1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV57851758; called by muse, mutect2
- PDE11A | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV53688826, COSV53706820; called by muse, mutect2, varscan2
- PDP1 | c.209G>C p.R70T | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV52603701; called by muse, mutect2, varscan2
- PDZD2 | c.5763G>C p.Q1921H | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1158358863, COSV56871085; called by muse, mutect2
- PHF2 | c.1770A>C p.E590D | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV63683603; called by muse, mutect2, varscan2
- PHF3 | c.4832C>T p.S1611L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV50337750; called by muse, mutect2, varscan2
- PKHD1L1 | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV65751564; called by muse, mutect2, varscan2
- PLA2G4C | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV62787668; called by muse, mutect2
- PLAT | c.608G>C p.C203S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54277756; called by muse, mutect2, varscan2
- PLCB1 | c.2293C>G p.Q765E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62066087, COSV62070873; called by muse, mutect2, varscan2
- PLXNA3 | c.4653G>C p.K1551N | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1557208611, COSV63755508; called by muse, mutect2, varscan2
- POU3F2 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60409540; called by muse, mutect2, varscan2
- PPP1CA | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs772793107, COSV56705011; called by muse, mutect2, varscan2
- PPP2R3C | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV54834892; called by muse, mutect2, varscan2
- PPP4R1 | c.101C>G p.S34* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV99552992; called by muse, mutect2
- PRDX4 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV65018895; called by muse, mutect2, varscan2
- PRKG1 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV64777003; called by muse, mutect2, varscan2
- PRR12 | c.1453C>G p.P485A (on ENST00000615927; = p.P1306A on NM_020719.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV69819965, COSV69820395; called by muse, mutect2, varscan2
- PSMC3IP | c.424G>C p.E142Q (on ENST00000393795 / NM_016556.4; = p.E130Q on NM_013290.6) | Missense Mutation (SNP) | VAF 11/327 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); catalogued as COSV53818805; called by muse, mutect2
- PTCHD3 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs746518651, COSV71256401, COSV71256933; called by muse, mutect2, varscan2
- PTPN13 | c.7420G>T p.E2474* (on ENST00000411767 / NM_080683.3; = p.E2455* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100363782; called by muse, mutect2, varscan2
- RAB27A | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV61017754; called by muse, mutect2, varscan2
- RAD1 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57715695; called by muse, mutect2, varscan2
- RANBP6 | c.3187G>A p.D1063N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV52391343, COSV99424309; called by muse, mutect2, varscan2
- RBBP4 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100542099; called by muse, mutect2
- RBM10 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556782040, COSV61308142, COSV61309495; called by muse, mutect2, varscan2
- RBM7 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.386); catalogued as COSV64955928; called by muse, mutect2, varscan2
- RBSN | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as rs892310059, COSV53791768; called by muse, mutect2
- RCHY1 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 15/114 reads (13%) | catalogued as COSV100185649; called by muse, mutect2, varscan2
- RELB | c.1403C>G p.S468C | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV55512658; called by muse, mutect2
- RESF1 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV57025200; called by muse, mutect2, varscan2
- RGS6 | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV59595127, COSV59596903; called by muse, mutect2, varscan2
- RHOU | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as COSV64209052; called by muse, mutect2
- RIF1 | c.4567G>C p.D1523H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54623260; called by muse, mutect2, varscan2
- RIF1 | c.5791G>C p.E1931Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.115); catalogued as COSV54623273; called by muse, mutect2
- RRP1 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV68544747; called by muse, mutect2, varscan2
- RRP15 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65117627; called by muse, mutect2
- RTTN | c.1014T>A p.S338R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as COSV55351181; called by muse, mutect2, varscan2
- RXFP2 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV53640475; called by muse, mutect2, varscan2
- RYR1 | c.3349G>A p.D1117N | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62109203; called by muse, mutect2, varscan2
- SAMD9L | c.3286G>C p.E1096Q | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV59084840; called by muse, mutect2
- SAPCD1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1180406600, COSV65174096; called by muse, mutect2
- SCAF8 | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65793625; called by muse, mutect2, varscan2
- SCAP | c.2663C>G p.S888* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99650034; called by muse, mutect2
- SEPTIN4 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV57899170; called by muse, mutect2, varscan2
- SESTD1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100090048; called by muse, mutect2, varscan2
- SHCBP1L | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as COSV62356882; called by muse, mutect2, varscan2
- SHOC1 | c.3121G>C p.E1041Q | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV59506666; called by muse, mutect2, varscan2
- SIGLEC1 | c.3467G>A p.R1156Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs368275865; called by muse, mutect2, varscan2
- SLC24A3 | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100038677; called by muse, mutect2, varscan2
- SLC30A2 | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 129/284 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV65333289; called by muse, mutect2, varscan2
- SLC7A14 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV99200270; called by muse, mutect2
- SLC9A2 | c.771C>G p.F257L | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.962); catalogued as COSV52131894, COSV52137183; called by muse, mutect2, varscan2
- SLC9A4 | c.2186G>C p.R729T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99762567, COSV99762662, COSV99762680; called by muse, mutect2
- SMO | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767352128, COSV50824141; called by muse, mutect2, varscan2
- SPHKAP | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV60871335; called by muse, mutect2, varscan2
- STAB1 | c.137C>G p.S46W | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV58742304; called by muse, mutect2
- STAT1 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs1245176183, COSV63116880; called by muse, mutect2
- STAT1 | c.1540C>T p.L514F | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100738924, COSV63117239, COSV63117311; called by muse, mutect2, varscan2
- SVEP1 | c.4526G>A p.R1509K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV57046155; called by muse, mutect2, varscan2
- SVIL | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as COSV63447681; called by muse, mutect2, varscan2
- SVIL | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV63447686; called by muse, mutect2, varscan2
- SYMPK | c.3295G>C p.E1099Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV55571836, COSV55575022; called by muse, mutect2
- SYTL4 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 18/109 reads (17%) | catalogued as COSV99342554; called by muse, mutect2, varscan2
- TEX15 | c.3200G>C p.R1067T (on ENST00000256246; = p.R1450T on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV56352791; called by muse, mutect2, varscan2
- TGIF2LX | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52213479; called by muse, mutect2, varscan2
- TLL2 | c.2420C>A p.S807Y | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV63575382; called by muse, mutect2
- TLL2 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV63571222, COSV63575395; called by muse, mutect2
- TMEM119 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV101219349; called by muse, mutect2, varscan2
- TMEM211 | c.396C>G p.F132L (on ENST00000423535; = p.F61L on NM_001001663.3) | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV66954388; called by muse, mutect2
- TMEM38A | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51820692, COSV51821585; called by muse, mutect2, varscan2
- TNKS | c.3240C>G p.I1080M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.588); catalogued as rs768586368, COSV60058092, COSV60067275; called by muse, mutect2
- TNRC6B | c.1621C>G p.Q541E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV100110842, COSV57306541; called by muse, mutect2, varscan2
- TPP2 | c.1709A>G p.H570R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.041); catalogued as COSV65754643; called by muse, mutect2, varscan2
- TPR | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as rs760168556, COSV66604465; called by muse, mutect2, varscan2
- TRAF2 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV56041105; called by muse, mutect2, varscan2
- TRAF2 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56041139; called by muse, mutect2
- TRAF3IP2 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV60677005; called by muse, mutect2, varscan2
- TRPM1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56641229; called by muse, mutect2, varscan2
- TRRAP | c.5857G>A p.E1953K (on ENST00000359863 / NM_001244580.1; = p.E1935K on NM_003496.3) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62853189; called by muse, mutect2, varscan2
- TTLL6 | c.1456G>A p.E486K (on ENST00000393382 / NM_001130918.3; = p.E179K on NM_173623.3) | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64979146; called by muse, mutect2
- TTN | c.14456C>T p.S4819L (on ENST00000591111; = p.S3892L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/119 reads (9%) | PolyPhen possibly damaging (0.452); catalogued as rs764310312, COSV59969202; called by muse, mutect2
- TTN | c.13634G>C p.R4545T (on ENST00000591111; = p.R3618T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | PolyPhen benign (0.068); catalogued as COSV60305678; called by muse, mutect2, varscan2
- UBR2 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100867289; called by muse, mutect2
- UHRF2 | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV52796027; called by muse, mutect2, varscan2
- VPS54 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV55444799; called by muse, mutect2, varscan2
- VWA5A | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs764811880, COSV104420786, COSV63708197; called by muse, mutect2, varscan2
- WAPL | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.083); catalogued as COSV53939613; called by muse, mutect2, varscan2
- WSB2 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV59574938; called by muse, mutect2, varscan2
- WWC1 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54657810; called by muse, mutect2
- XIRP2 | c.583G>C p.E195Q (on ENST00000628543; = p.E370Q on NM_152381.6) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54715914, COSV54728124; called by muse, mutect2, varscan2
- XYLT2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV50016708, COSV99190494; called by muse, mutect2, varscan2
- ZAN | c.6725C>G p.S2242C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV61815366; called by muse, mutect2, varscan2
- ZC3H12A | c.758G>C p.R253P | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66104522; called by muse, mutect2, varscan2
- ZDHHC9 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100852225, COSV64097366; called by muse, mutect2, varscan2
- ZMYND8 | c.756C>G p.I252M (on ENST00000311275 / NM_001363741.2; = p.I272M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV53683528, COSV53695521; called by muse, mutect2, varscan2
- ZNF160 | c.1334G>C p.R445T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.924); catalogued as COSV62000767; called by muse, mutect2, varscan2
- ZNF160 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.455); catalogued as COSV62000771, COSV62001298; called by muse, mutect2, varscan2
- ZNF160 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV62000775; called by muse, varscan2
- ZNF160 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1302031241, COSV62000778; called by muse, varscan2
- ZNF221 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as COSV52110998; called by muse, mutect2
- ZNF226 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771774187, COSV100335104, COSV56197859; called by muse, mutect2
- ZNF229 | c.1854T>G p.H618Q | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52164550; called by muse, mutect2
- ZNF229 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as COSV52164558; called by muse, mutect2
- ZNF229 | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); catalogued as COSV52164567; called by muse, mutect2, varscan2
- ZNF229 | c.291C>G p.F97L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52161823; called by muse, mutect2
- ZNF420 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.662); catalogued as COSV58496140; called by muse, mutect2
- ZNF665 | c.1247C>G p.S416C (on ENST00000600412; = p.S481C on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV67217272; called by muse, mutect2, varscan2
- ZNF665 | c.545C>T p.S182L (on ENST00000600412; = p.S247L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV67217281; called by muse, mutect2, varscan2
- ZNF701 | c.526G>A p.E176K (on ENST00000301093; = p.E110K on NM_018260.3) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.836); catalogued as COSV56526933; called by muse, mutect2
- ZNF835 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV73379723; called by muse, mutect2, varscan2
- AKNA | c.3144del p.A1049Pfs*123 | Frame Shift Del (DEL) | VAF 21/123 reads (17%) | called by mutect2, pindel, varscan2
- ARID1A | c.2090dup p.S698Vfs*119 | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- SLC47A2 | c.348_349del p.L117Gfs*88 | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | called by pindel, varscan2
- STXBP1 | c.294del p.K98Nfs*22 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- SYNRG | c.3756G>T p.L1252F | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMPH | c.916C>T p.L306= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs536894640, COSV57755078; called by muse, mutect2, varscan2
- ANK1 | c.2544G>A p.P848= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as rs777453775, COSV55872574; called by muse, mutect2
- ATAD5 | c.1663C>T p.L555= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV58972631, COSV58978300; called by muse, mutect2
- BAIAP2 | c.1081C>T p.L361= | Silent (SNP) | VAF 51/203 reads (25%) | catalogued as COSV58340115; called by muse, mutect2, varscan2
- BPIFB6 | c.27C>T p.L9= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV62756534; called by muse, mutect2, varscan2
- BTBD2 | c.1575C>G p.T525= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV55310420; called by muse, mutect2, varscan2
- C6 | c.1746G>A p.K582= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV54709011; called by muse, mutect2
- C9orf85 | c.42G>A p.Q14= | Silent (SNP) | VAF 41/366 reads (11%) | catalogued as COSV58255897; called by muse, mutect2, varscan2
- CALCRL | c.432G>A p.L144= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV66476168, COSV66477145; called by muse, mutect2, varscan2
- CAPN3 | c.1452G>A p.L484= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- CDK5RAP1 | c.1224T>A p.R408= (on ENST00000357886 / NM_001365728.1; = p.R394= on NM_016082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as COSV59428744; called by muse, mutect2
- CEACAM19 | c.522C>T p.I174= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV62552282; called by muse, mutect2, varscan2
- CELSR1 | c.5115G>C p.L1705= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV53098849; called by muse, mutect2, varscan2
- CEP57 | c.120T>C p.P40= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV57690211; called by muse, mutect2, varscan2
- CFAP74 | c.1173G>A p.L391= | Silent (SNP) | VAF 24/257 reads (9%) | catalogued as rs1273776161, COSV54573228; called by muse, mutect2
- COG5 | c.462C>G p.L154= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV51762596; called by muse, mutect2, varscan2
- COL12A1 | c.852C>G p.L284= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV59406489; called by muse, mutect2, varscan2
- CPB1 | c.1005G>A p.V335= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1402054466, COSV51573459, COSV51576600; called by mutect2, varscan2
- CSF3R | c.1902C>T p.G634= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58971332; called by muse, mutect2, varscan2
- CTNNA2 | c.255C>G p.L85= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV63598408; called by muse, mutect2, varscan2
- CYP4F8 | c.1224C>T p.L408= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV57855264; called by muse, mutect2, varscan2
- DCAF17 | c.225C>T p.V75= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV64545970; called by muse, mutect2, varscan2
- DEPDC1B | c.132C>T p.F44= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV54012804; called by muse, mutect2, varscan2
- DPH1 | c.351G>A p.A117= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs1480455126, COSV53986407, COSV99559500; called by muse, mutect2, varscan2
- DQX1 | c.1317G>A p.L439= | Silent (SNP) | VAF 32/290 reads (11%) | catalogued as COSV66353628; called by muse, mutect2, varscan2
- DUS1L | c.903C>T p.I301= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1232383593, COSV57651192; called by muse, mutect2, varscan2
- EGF | c.1521C>A p.L507= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV54483888; called by muse, mutect2, varscan2
- FADS1 | c.969C>T p.F323= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV63521089; called by muse, mutect2
- FERMT2 | c.792G>C p.V264= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV58409106; called by muse, mutect2
- FTSJ3 | c.96G>A p.L32= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV59563870; called by muse, mutect2, varscan2
- GNAT1 | c.837C>T p.L279= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs368618734, COSV51698967; called by muse, mutect2, varscan2
- H3C10 | c.99C>T p.T33= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV60798679; called by muse, mutect2
- HIVEP3 | c.2985G>A p.Q995= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV56022548; called by muse, mutect2
- IKZF1 | c.510G>A p.E170= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100497785, COSV58786799; called by muse, mutect2
- IL10RA | c.129C>G p.L43= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV57142000; called by muse, mutect2, varscan2
- IRF2BP1 | c.1278G>C p.L426= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV56194937; called by muse, mutect2
- IRF2BP2 | c.573C>G p.L191= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV64015599; called by muse, mutect2
- JPH3 | c.480G>C p.L160= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV52473390; called by muse, mutect2, varscan2
- KMT2C | c.81G>A p.P27= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100064128; called by muse, mutect2
- LOXL2 | c.1311G>A p.L437= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs746826821, COSV66692357; called by muse, mutect2, varscan2
- LRP5 | c.3159G>A p.L1053= | Silent (SNP) | VAF 61/193 reads (32%) | catalogued as COSV53722884; called by muse, mutect2, varscan2
- LTBP1 | c.2352G>A p.L784= (on ENST00000404816 / NM_206943.4; = p.L458= on NM_000627.4) | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100615967; called by muse, mutect2
- MAGEC1 | c.1479T>C p.S493= | Silent (SNP) | VAF 29/208 reads (14%) | catalogued as COSV53580293; called by muse, mutect2, varscan2
- MED10 | c.84C>T p.D28= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99740153; called by muse, mutect2
- MFAP3L | c.402G>T p.V134= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as rs749896717, COSV64372984; called by muse, mutect2, varscan2
- MID2 | c.504C>T p.A168= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV53313434; called by muse, mutect2, varscan2
- MIEN1 | c.105C>T p.F35= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV54081413; called by muse, mutect2, varscan2
- MLH1 | c.783C>T p.F261= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs768119795, COSV99212287; called by muse, mutect2
- MOCOS | c.1167C>T p.I389= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV54346453; called by muse, mutect2
- MYO18A | c.1935G>A p.L645= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs967985798, COSV62872597; called by muse, mutect2, varscan2
- NEPRO | c.396G>A p.V132= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV58724430; called by muse, mutect2, varscan2
- NR1I2 | c.264G>A p.R88= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV61979593; called by muse, mutect2, varscan2
- NRAP | c.4674C>T p.D1558= (on ENST00000359988 / NM_001322945.2; = p.D1523= on NM_006175.4) | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV63493549; called by muse, mutect2, varscan2
- NRARP | c.309C>T p.L103= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100751927; called by muse, mutect2
- NUP133 | c.789T>C p.F263= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs201054748; called by muse, mutect2, varscan2
- OPLAH | c.639C>T p.F213= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV101470687; called by muse, mutect2, varscan2
- OR2G3 | c.99C>T p.F33= | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as COSV60682979; called by muse, mutect2
- PACSIN2 | c.447G>A p.L149= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV54322996; called by muse, mutect2, varscan2
- PCDHA9 | c.171G>A p.A57= | Silent (SNP) | VAF 97/241 reads (40%) | catalogued as COSV65332031, COSV65334297; called by muse, mutect2, varscan2
- PCDHGA6 | c.2295G>A p.K765= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV54020403; called by muse, mutect2, varscan2
- PDE4DIP | c.6882G>A p.Q2294= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs782605441, COSV57725584; called by muse, varscan2
- PDS5B | c.1653G>A p.Q551= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100220286; called by muse, mutect2
- PDS5B | c.2733C>A p.I911= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV59733659; called by muse, mutect2, varscan2
- PDZD4 | c.243C>T p.I81= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV51250706; called by muse, varscan2
- PGLYRP3 | c.804C>T p.F268= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99319399; called by muse, mutect2
- POP4 | c.207G>A p.K69= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV55677356; called by muse, mutect2, varscan2
- PRAMEF12 | c.1134C>T p.L378= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as rs920024998, COSV63216545; called by muse, mutect2, varscan2
- PRAMEF14 | c.840C>T p.F280= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- PRMT9 | c.447G>A p.V149= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV59361278; called by muse, mutect2, varscan2
- PRPS2 | c.96G>C p.T32= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV101028270; called by muse, mutect2, varscan2
- PTPN13 | c.6741T>G p.L2247= (on ENST00000411767 / NM_080683.3; = p.L2228= on NM_006264.3) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV57416254; called by muse, mutect2, varscan2
- PTPRZ1 | c.3039G>A p.L1013= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV101100471, COSV66444562; called by muse, mutect2
- PTPRZ1 | c.3243G>A p.L1081= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV66444569; called by muse, mutect2, varscan2
- RGL1 | c.9G>A p.V3= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs768678965, COSV58994983; called by muse, mutect2, varscan2
- RIPK3 | c.363G>A p.L121= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as COSV53477286; called by muse, mutect2, varscan2
- RPL3 | c.360G>A p.K120= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs1446095869, COSV53365084, COSV53366483; called by muse, mutect2, varscan2
- RPS6KC1 | c.3081C>G p.L1027= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV65302417; called by muse, mutect2, varscan2
- SCN7A | c.3991C>T p.L1331= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV69274335; called by muse, mutect2, varscan2
- SCO2 | c.99G>C p.L33= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV52689296; called by muse, mutect2, varscan2
- SIPA1L3 | c.1584G>A p.V528= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV55923020; called by muse, mutect2
- SIPA1L3 | c.3768C>T p.N1256= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1354650255, COSV55923030; called by muse, mutect2
- SLC30A4 | c.315G>A p.L105= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs1449446670, COSV56007337; called by muse, varscan2
- SLC30A4 | c.264G>A p.L88= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV56007350; called by muse, varscan2
- SLMAP | c.1887C>T p.L629= (on ENST00000428312 / NM_001377924.1; = p.L691= on NM_007159.5) | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs1387015857, COSV55852609; called by muse, mutect2, varscan2
- SMC1A | c.1707C>T p.T569= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs782653434, COSV59131660; called by muse, mutect2, varscan2
- SNX32 | c.1179G>A p.R393= | Silent (SNP) | VAF 54/219 reads (25%) | catalogued as COSV57450505; called by muse, mutect2, varscan2
- SPOP | c.60G>A p.E20= | Silent (SNP) | VAF 11/161 reads (7%) | catalogued as rs1174659692, COSV61655573; called by muse, mutect2
- SPPL2C | c.690G>A p.L230= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as rs774523527, COSV61293617; called by muse, mutect2, varscan2
- STPG2 | c.837G>A p.K279= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- SUPT20HL1 | c.1305C>G p.L435= | Silent (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- TANC2 | c.2244C>G p.L748= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV67344024; called by muse, mutect2
- TG | c.7872G>A p.L2624= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1224384170, COSV55092253; called by muse, mutect2, varscan2
- TLL2 | c.15T>C p.T5= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1453057863, COSV63575401; called by muse, mutect2, varscan2
- TRAF2 | c.831G>A p.K277= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as rs1043853831, COSV56041125; called by muse, mutect2
- TTN | c.10293G>A p.L3431= (on ENST00000591111; = p.L3385= on NM_003319.4) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV60305695; called by muse, mutect2, varscan2
- WDR90 | c.4290C>T p.L1430= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99552443; called by muse, mutect2, varscan2
- WDR90 | c.4443C>G p.L1481= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV53474780; called by muse, mutect2, varscan2
- WNT3 | c.795C>T p.L265= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV56646988; called by muse, mutect2, varscan2
- YRDC | c.555G>A p.Q185= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV100888547; called by muse, mutect2
- ZBTB9 | c.72G>A p.Q24= | Silent (SNP) | VAF 41/206 reads (20%) | catalogued as COSV67702390; called by muse, mutect2, varscan2
- ZDHHC9 | c.558C>T p.L186= | Silent (SNP) | VAF 99/139 reads (71%) | catalogued as COSV64097369; called by muse, mutect2, varscan2
- ZNF343 | c.1608C>T p.L536= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as COSV53855408; called by muse, mutect2, varscan2
- ZNF594 | c.1071C>T p.F357= | Silent (SNP) | VAF 69/203 reads (34%) | catalogued as COSV68386113; called by muse, mutect2, varscan2
- ZRSR2 | c.66G>A p.L22= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV57064283; called by muse, mutect2, varscan2
- ARMC12 | c.163+54G>A | Intron (SNP) | VAF 17/78 reads (22%) | catalogued as rs572856258, COSV55359228; called by muse, mutect2, varscan2
- BLOC1S2 | c.*1G>C | 3'UTR (SNP) | VAF 35/103 reads (34%) | catalogued as rs1257956567, COSV100951780; called by muse, mutect2, varscan2
- GCNT2 | c.926-35341del | Intron (DEL) | VAF 51/177 reads (29%) | catalogued as COSV53944152, COSV99399612; called by mutect2, pindel, varscan2
- GNAO1 | c.723+4039G>T | Intron (SNP) | VAF 86/363 reads (24%) | catalogued as COSV52612824, COSV52619519; called by muse, mutect2, varscan2
- LINC02872 | n.366G>C | RNA (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- MIR411 | n.32G>T | RNA (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- MOG | c.593-64G>C | Intron (SNP) | VAF 28/132 reads (21%) | catalogued as COSV65306894; called by muse, mutect2, varscan2
- PAQR6 | c.760+30G>C | Intron (SNP) | VAF 12/81 reads (15%) | catalogued as COSV52746621; called by muse, mutect2, varscan2
- SNORD116-25 | n.77C>T | RNA (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- TMEM181 | c.-48G>A | 5'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1032087062; called by muse, mutect2, varscan2
- VEGFA | chr6:43771169 G>T | 5'Flank (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100035093; called by muse, varscan2
